Somatic mutation profile of tumor specimen 0DX7FS from CCDI case PBCPXP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoma in pleomorphic adenoma; Tissue or organ of origin: Parotid gland; Age at diagnosis: 5.7 years (2,079 days).
Specimen 0DX7FS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffd941f7-f74e-462f-8c20-35d5c737f7be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX7EU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d98a80f0-a335-47ee-8675-1770144986aa

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFHR1 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 26/451 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.029); called by muse, mutect2
- FAM114A2 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 246/588 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MGARP | c.446C>A p.T149N | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- MYO7A | c.544C>G p.H182D | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RAB11FIP4 | c.1133+33G>A | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as rs748124830; called by mutect2, varscan2
